Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAFE, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAFE-01A (Primary Tumor).

Department of Pathology

ICD-O-3
Seminoma NOS 9061/3
Site: (L) Testis NOS C62.9
p13 2/3/14

Direct dial
Mobile:
Internal postal address
E-mail
Date

Concerning

Summary pathology report

Left orchidectomy; seminoma; diameter 4 cm; tumor confined to testis in available slides;
angio-invasion present; no invasion in rete testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file c6ebaf07-8200-4fd5-a810-cc10674b1ab3 (TCGA-2G-AAFE.414A04CE-E608-48CB-86B6-BF901F888D28.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).